Gene-level copy-number profile of tumor specimen TCGA-BR-8289-01A from TCGA case TCGA-BR-8289, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 57.1 years (20,849 days).
Specimen TCGA-BR-8289-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.bbbe5334-3efc-4251-b5c0-a26af158a2d0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8289-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/16a9bbfd-f625-4f19-814b-8de8b8212b55

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,579; copy number 2: 2,549; copy number 3: 14,849; copy number 4: 23,611; copy number 5: 7,536; copy number 6: 4,559; copy number 7: 3,700; copy number 8: 649; copy number 9: 459; copy number 10: 71; copy number 11: 40; copy number 12: 22; copy number 13: 28; copy number 14: 14; copy number 25: 39; copy number 26: 1; copy number 27: 4; copy number 28: 32; copy number 41: 13; copy number 43: 14; copy number 54: 38.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8289-01A-11D-2338-01): tumor purity 0.5, ploidy 3.81, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,321,663–246,322,438, 1 gene: SMYD3-IT1.
- chr3:60,616,822–60,732,636, 5 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr12:66,563,524–66,569,194, 2 genes: OSBPL9P5, OSBPL9P4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 775 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:206,767,602–207,184,062, 18 genes, copy number 13 (within-gene range 7–13): IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2.
- chr1:234,629,311–235,328,219, 22 genes, copy number 12 (within-gene range 7–12): LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3, LINC01348, AL732292.1, AL732292.2, TOMM20, SNORA14B, RBM34, ARID4B, MIR4753.
- chr1:236,348,257–236,921,278, 10 genes, copy number 11: EDARADD, ENO1P1, LGALS8, LGALS8-AS1, AL359921.2, AL359921.1, HEATR1, ACTN2, MTR, RPSAP21.
- chr2:43,001,355–43,233,394, 10 genes, copy number 13: AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126, AC010883.1.
- chr3:157,081,667–185,153,060, 428 genes, copy number 9 (broad region; genes not listed).
- chr4:132,985,510–132,988,677, 1 gene, copy number 28: AC110751.1.
- chr6:95,575,183–96,015,391, 5 genes, copy number 10: MANEA-DT, MANEA, AL607077.1, AL034348.1, KRT18P50.
- chr6:168,820,423–169,102,428, 7 genes, copy number 11: AL513210.2, AL513210.1, AL109924.4, AL109924.3, AL109924.1, AL109924.2, AL136129.1.
- chr7:70,972–896,435, 23 genes, copy number 10 (within-gene range 7–10): AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1.
- chr8:11,136,898–11,896,870, 29 genes, copy number 54: AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, AF131216.5, BLK, AC022239.1, LINC00208, AC022239.2, GATA4, C8orf49, NEIL2, SUB1P1, FDFT1, AC069185.1, CTSB, AC025857.1.
- chr8:12,676,035–13,909,780, 26 genes, copy number 27–54: AC068587.1, OR7E8P, OR7E15P, OR7E10P, MIR5692A2, LONRF1, MIR3926-1, MIR3926-2, AC123777.1, LINC00681, TRMT9B, AC135352.1, RNU6-842P, DLC1, AC106845.1, Y_RNA, AC019270.1, MTND4P7, RNA5SP255, C8orf48, AC022832.1, AC022832.2, AC022880.2, AC022880.1, AC022690.2, AC022690.1.
- chr8:17,469,518–18,401,218, 30 genes, copy number 28: ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1, ASAH1, AC124242.1, AC124242.2, AC124242.3, NAT1, MTND4LP26, NATP, AC025062.1, AC025062.3, AC025062.2, NAT2.
- chr8:18,720,905–18,734,405, 1 gene, copy number 28: AC100800.1.
- chr8:23,600,026–23,600,138, 1 gene, copy number 26: RNU4-71P.
- chr8:37,326,575–38,601,200, 53 genes, copy number 25–43: AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1.
- chr12:56,101,331–56,163,496, 11 genes, copy number 11 (within-gene range 4–11): AC034102.2, PA2G4, AC034102.4, RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6.
- chr17:50,543,058–51,260,163, 31 genes, copy number 9 (within-gene range 5–9): SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9, AC005920.2, NME1, NME1-NME2, NME2, MBTD1, AC005839.1, AC006141.1.
- chr19:27,638,483–30,016,612, 57 genes, copy number 10–14 (within-gene range 8–14): ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32.
- chr20:50,081,124–50,479,991, 12 genes, copy number 11 (within-gene range 7–11): PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2.

Autosomal genes at a single copy (total copy number 1): 1,574. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
